Gene-level copy-number profile of tumor specimen TCGA-09-1669-01A from TCGA case TCGA-09-1669, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 54.9 years (20,052 days).
Specimen TCGA-09-1669-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.0fa8feb6-7f0c-4f3e-8f45-efa5baa423bd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-1669-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ac192a86-0438-46d1-bb29-c548e0177213

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 77; copy number 2: 13,303; copy number 3: 5,320; copy number 4: 28,712; copy number 5: 2,326; copy number 6: 8,580; copy number 7: 321; copy number 8: 573; copy number 9: 301; copy number 10: 40; copy number 11: 76; copy number 12: 59; copy number 14: 112; copy number 20: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-09-1669-01): tumor purity 0.9, ploidy 2, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:128,944,628–128,944,956, 1 gene: AC093783.1.
- chr13:48,303,744–48,599,436, 1 gene (within-gene range 0–4): RB1.
- chr13:48,340,797–48,444,704, 3 genes: AL392048.1, LPAR6, Metazoa_SRP.
- chr17:31,272,013–31,321,749, 4 genes: OMG, EVI2B, AC134669.1, EVI2A.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 589 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:119,146,151–119,205,143, 3 genes, copy number 10 (within-gene range 4–10): TEX55, AC083800.1, UPK1B.
- chr3:126,213,204–126,247,714, 1 gene, copy number 9 (within-gene range 4–9): AC079848.2.
- chr3:151,873,643–151,884,619, 1 gene, copy number 20: SUCNR1.
- chr3:174,631,823–174,632,064, 1 gene, copy number 11: RN7SKP40.
- chr3:177,816,865–178,172,449, 5 genes, copy number 10 (within-gene range 6–10): LINC02015, AC007953.1, AC007953.2, RNU6-1120P, AC110992.1.
- chr3:179,148,114–179,240,093, 1 gene, copy number 14 (within-gene range 6–14): PIK3CA.
- chr6:167,607–16,766,883, 300 genes, copy number 9 (broad region; genes not listed).
- chr7:138,002,324–138,118,305, 1 gene, copy number 11 (within-gene range 6–11): AKR1D1.
- chr7:138,046,654–141,480,380, 74 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr8:124,539,101–139,127,953, 170 genes, copy number 12–14 (broad region; genes not listed).
- chr10:22,252,072–23,586,224, 30 genes, copy number 10: AL158211.5, AL158211.1, RPL31P45, COMMD3, COMMD3-BMI1, BMI1, AL158211.4, AL158211.2, AL158211.3, SPAG6, AL513128.1, AL513128.3, AL513128.2, PIP4K2A, AL390318.1, RNU6-413P, ARMC3, AL139815.1, RNA5SP304, MSRB2, YWHAZP3, AL139281.2, PTF1A, C10orf67, AL139281.1, AL606469.1, AL606469.2, OTUD1, AL512603.2, AL512603.1.
- chr15:33,310,962–33,866,121, 2 genes, copy number 10 (within-gene range 2–10): RYR3, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 77. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
